Somatic mutation profile of tumor specimen TCGA-DM-A1D0-01A (aliquot TCGA-DM-A1D0-01A-11D-A152-10) from TCGA case TCGA-DM-A1D0, project TCGA-COAD (Colon Adenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Sigmoid colon; AJCC pathologic stage: Stage IIA; Age at diagnosis: 79.1 years (28,875 days).
Specimen TCGA-DM-A1D0-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 31be88b5-7641-403e-a522-3cad10b94829.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-DM-A1D0-10A (Blood Derived Normal), aliquot TCGA-DM-A1D0-10A-01D-A152-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/58d9d5a3-8b77-4de1-b657-8e9bb5b25a90

The open-access MAF lists 130 somatic variants for this specimen: 91 protein-altering or splice-affecting, 35 silent, 4 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 77, Silent 35, Nonsense Mutation 4, Frame Shift Del 3, Splice Site 3, RNA 3, Frame Shift Ins 2, Intron 1, Splice Region 1, In Frame Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- APC | c.4222G>T p.E1408* | Nonsense Mutation (SNP) | VAF 123/143 reads (86%) | hotspot (GDC flag); catalogued as CM106374, COSV57326063, COSV57397024; called by muse, mutect2, varscan2
- KRAS | c.35G>T p.G12V | Missense Mutation (SNP) | VAF 87/203 reads (43%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as rs121913529, COSV55497369, COSV55497419, COSV55497479; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- TP53 | c.919+2T>G p.X307_splice | Splice Site (SNP) | VAF 20/26 reads (77%) | hotspot (GDC flag); catalogued as rs1131691016, COSV52698436, COSV52737448, COSV52774697; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ABCA1 | c.2996G>A p.R999H | Missense Mutation (SNP) | VAF 13/35 reads (37%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.982); catalogued as rs150371991, COSV66064245; called by muse, mutect2, varscan2
- AC097637.1 | c.59T>A p.I20N | Missense Mutation (SNP) | VAF 21/64 reads (33%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); catalogued as COSV59725882; called by muse, mutect2, varscan2
- ALMS1 | c.3631A>G p.I1211V | Missense Mutation (SNP) | VAF 43/112 reads (38%) | SIFT tolerated (0.19); PolyPhen benign (0.005); catalogued as rs758717223, COSV52504167; called by muse, mutect2, varscan2
- AMMECR1 | c.764A>G p.Y255C | Missense Mutation (SNP) | VAF 31/116 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV53316425; called by muse, mutect2, varscan2
- ASCC3 | c.489dup p.G164Wfs*2 | Frame Shift Ins (INS) | VAF 48/154 reads (31%) | catalogued as rs747570359; called by mutect2, varscan2
- ATP6V1D | c.314C>A p.T105N | Missense Mutation (SNP) | VAF 179/209 reads (86%) | SIFT tolerated (0.32); PolyPhen benign (0.033); catalogued as COSV53598890; called by muse, mutect2, varscan2
- ATRX | c.5817A>T p.K1939N | Missense Mutation (SNP) | VAF 30/356 reads (8%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.629); catalogued as COSV100969996; called by muse, mutect2
- C1S | c.1327G>A p.D443N | Missense Mutation (SNP) | VAF 38/99 reads (38%) | SIFT tolerated (0.55); PolyPhen benign (0.025); catalogued as rs781845594, COSV61070239; called by muse, mutect2, varscan2
- CCDC97 | c.533G>A p.R178Q | Missense Mutation (SNP) | VAF 23/68 reads (34%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.998); catalogued as rs752646666, COSV54189651; called by muse, mutect2, varscan2
- CELA2A | c.377A>C p.K126T | Missense Mutation (SNP) | VAF 33/108 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV62747257; called by muse, mutect2, varscan2
- DIP2A | c.218C>T p.T73M | Missense Mutation (SNP) | VAF 44/92 reads (48%) | SIFT tolerated (0.08); PolyPhen benign (0.276); catalogued as rs776355835, COSV59473325; called by muse, mutect2, varscan2
- EPHA3 | c.934C>T p.R312W | Missense Mutation (SNP) | VAF 27/57 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs746351940, COSV100342698, COSV60696147; called by muse, mutect2, varscan2
- FAT1 | c.3004A>T p.R1002W | Missense Mutation (SNP) | VAF 32/86 reads (37%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.855); catalogued as COSV71672296; called by muse, mutect2, varscan2
- FLG | c.5099G>C p.R1700T | Missense Mutation (SNP) | VAF 64/157 reads (41%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.579); catalogued as rs1455886217, COSV100910467; called by muse, mutect2, varscan2
- FLRT2 | c.838C>T p.R280W | Missense Mutation (SNP) | VAF 47/57 reads (82%) | SIFT deleterious (0); PolyPhen probably damaging (0.925); catalogued as rs148371022, COSV58149138; called by muse, mutect2, varscan2
- GK2 | c.1419C>A p.S473R | Missense Mutation (SNP) | VAF 47/112 reads (42%) | SIFT tolerated (0.09); PolyPhen benign (0.012); catalogued as COSV62626225; called by muse, mutect2, varscan2
- GLRA4 | c.358G>C p.D120H | Missense Mutation (SNP) | VAF 11/119 reads (9%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.451); catalogued as COSV65455279, COSV65455687; called by muse, mutect2
- GOLM1 | c.539_540insT p.K180Nfs*4 | Frame Shift Ins (INS) | VAF 34/230 reads (15%) | catalogued as COSV57413786, COSV57413907; called by mutect2, varscan2
- GRAMD1C | c.1541G>A p.R514Q | Missense Mutation (SNP) | VAF 38/88 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.92); catalogued as rs770757111, COSV63982007; called by muse, mutect2, varscan2
- HAUS3 | c.1175A>G p.E392G | Missense Mutation (SNP) | VAF 20/164 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.853); catalogued as COSV54721951; called by muse, mutect2, varscan2
- HBE1 | c.90C>A p.G30= | Splice Region (SNP) | VAF 18/52 reads (35%) | catalogued as COSV53079637; called by muse, mutect2, varscan2
- HSPA12A | c.1361C>T p.P454L | Missense Mutation (SNP) | VAF 15/26 reads (58%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs782777572, COSV65021024; called by muse, mutect2, varscan2
- IBTK | c.779A>T p.Q260L | Missense Mutation (SNP) | VAF 9/78 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV60391269; called by muse, mutect2, varscan2
- IFI35 | c.793G>T p.V265L (on ENST00000415816 / NM_001330230.2; = p.V267L on NM_005533.5) | Missense Mutation (SNP) | VAF 37/109 reads (34%) | SIFT deleterious (0); PolyPhen benign (0.045); catalogued as COSV55895970; called by muse, mutect2, varscan2
- IFT140 | c.1900A>G p.K634E | Missense Mutation (SNP) | VAF 10/116 reads (9%) | SIFT tolerated (0.46); PolyPhen benign (0.003); catalogued as COSV68486303; called by muse, mutect2
- IGSF9B | c.4018A>G p.S1340G | Missense Mutation (SNP) | VAF 10/14 reads (71%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0); catalogued as COSV100316922; called by muse, mutect2, varscan2
- KCNE5 | c.47T>A p.L16Q | Missense Mutation (SNP) | VAF 19/42 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV64508261; called by muse, mutect2, varscan2
- KCNH7 | c.298C>G p.H100D | Missense Mutation (SNP) | VAF 33/89 reads (37%) | SIFT deleterious (0.02); PolyPhen benign (0.359); catalogued as COSV59787984; called by muse, mutect2, varscan2
- KCNN3 | c.1708G>A p.V570I (on ENST00000618040 / NM_001204087.1; = p.V555I on NM_002249.6) | Missense Mutation (SNP) | VAF 22/63 reads (35%) | SIFT deleterious (0.01); PolyPhen benign (0.388); catalogued as COSV55213238; called by muse, mutect2, varscan2
- KCNU1 | c.2404C>T p.P802S | Missense Mutation (SNP) | VAF 40/52 reads (77%) | SIFT tolerated (0.92); PolyPhen benign (0.005); catalogued as COSV101299008, COSV67753627; called by muse, mutect2, varscan2
- KIDINS220 | c.5047G>A p.V1683M | Missense Mutation (SNP) | VAF 38/299 reads (13%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.022); catalogued as rs367740187; called by muse, mutect2, varscan2
- KRT28 | c.1088G>C p.R363T | Missense Mutation (SNP) | VAF 28/163 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV60683805, COSV60684681; called by mutect2, varscan2
- LRCH2 | c.1108A>T p.S370C | Missense Mutation (SNP) | VAF 82/185 reads (44%) | SIFT deleterious (0); PolyPhen possibly damaging (0.908); catalogued as COSV57746917; called by muse, mutect2, varscan2
- MED16 | c.705C>G p.S235R | Missense Mutation (SNP) | VAF 13/27 reads (48%) | SIFT tolerated (0.47); PolyPhen probably damaging (0.997); catalogued as COSV54123900; called by muse, mutect2, varscan2
- MROH5 | c.3040C>T p.R1014C | Missense Mutation (SNP) | VAF 39/147 reads (27%) | SIFT deleterious (0); PolyPhen benign (0.233); catalogued as rs754182427, COSV71300552; called by muse, mutect2, varscan2
- NEK8 | c.2002G>A p.V668M | Missense Mutation (SNP) | VAF 20/76 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as COSV52043268; called by muse, mutect2, varscan2
- NMT1 | c.1388A>T p.E463V | Missense Mutation (SNP) | VAF 44/127 reads (35%) | SIFT tolerated (0.07); PolyPhen benign (0.087); catalogued as COSV51958529; called by muse, mutect2, varscan2
- NXPH2 | c.215C>T p.A72V | Missense Mutation (SNP) | VAF 30/106 reads (28%) | SIFT tolerated (0.11); PolyPhen benign (0.015); catalogued as COSV55640382; called by muse, mutect2, varscan2
- OPN3 | c.193C>T p.L65F | Missense Mutation (SNP) | VAF 17/43 reads (40%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.99); catalogued as COSV59362867; called by muse, mutect2, varscan2
- OR2L8 | c.506G>A p.R169Q | Missense Mutation (SNP) | VAF 16/210 reads (8%) | SIFT tolerated (0.51); PolyPhen benign (0.023); catalogued as rs565612069, COSV100594400, COSV61727112; called by muse, mutect2
- OR5F1 | c.243G>C p.M81I | Missense Mutation (SNP) | VAF 36/185 reads (19%) | SIFT deleterious (0.01); PolyPhen benign (0.184); catalogued as COSV53545492; called by muse, mutect2, varscan2
- PCDH11X | c.1967G>A p.S656N | Missense Mutation (SNP) | VAF 201/516 reads (39%) | SIFT tolerated (0.06); PolyPhen benign (0.219); catalogued as COSV100008015, COSV100011954; called by muse, mutect2, varscan2
- PCDHGA5 | c.215C>T p.T72M | Missense Mutation (SNP) | VAF 34/80 reads (43%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.223); catalogued as rs969188576, COSV53908808; called by muse, mutect2, varscan2
- PDCD11 | c.3475-1G>A p.X1159_splice | Splice Site (SNP) | VAF 113/169 reads (67%) | catalogued as COSV63933200; called by muse, mutect2, varscan2
- PDCD4 | c.1210-1G>C p.X404_splice | Splice Site (SNP) | VAF 26/65 reads (40%) | catalogued as COSV99700754; called by muse, mutect2, varscan2
- PLCXD3 | c.562G>A p.D188N | Missense Mutation (SNP) | VAF 33/89 reads (37%) | SIFT tolerated (0.19); PolyPhen benign (0.001); catalogued as COSV60605685, COSV60613758; called by muse, mutect2, varscan2
- PLS3 | c.299A>C p.K100T | Missense Mutation (SNP) | VAF 104/259 reads (40%) | SIFT tolerated (0.05); PolyPhen benign (0.15); catalogued as COSV56776661; called by muse, mutect2, varscan2
- POM121C | c.3685A>C p.K1229Q (on ENST00000607367; = p.K987Q on NM_001099415.3) | Missense Mutation (SNP) | VAF 74/211 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV57544453, COSV57545991; called by muse, mutect2, varscan2
- PSMD3 | c.940C>T p.R314C | Missense Mutation (SNP) | VAF 55/608 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1319609259, COSV52856489; called by muse, mutect2
- PWWP3B | c.697G>C p.D233H | Missense Mutation (SNP) | VAF 47/107 reads (44%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.824); catalogued as COSV61798541; called by muse, mutect2, varscan2
- PYHIN1 | c.1022C>T p.T341M | Missense Mutation (SNP) | VAF 83/238 reads (35%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.761); catalogued as rs373907087; called by muse, mutect2, varscan2
- RESF1 | c.1250A>G p.N417S | Missense Mutation (SNP) | VAF 29/89 reads (33%) | SIFT tolerated (0.06); PolyPhen benign (0.391); catalogued as rs144248952; called by muse, mutect2, varscan2
- RGS17 | c.372G>T p.Q124H | Missense Mutation (SNP) | VAF 106/250 reads (42%) | SIFT tolerated (0.09); PolyPhen benign (0); catalogued as COSV52806355; called by muse, mutect2, varscan2
- RNF215 | c.620G>T p.G207V | Missense Mutation (SNP) | VAF 22/32 reads (69%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.916); catalogued as COSV99306369; called by muse, mutect2, varscan2
- RNF220 | c.816G>C p.L272F | Missense Mutation (SNP) | VAF 8/98 reads (8%) | SIFT tolerated (0.23); PolyPhen probably damaging (0.969); catalogued as COSV100698301; called by muse, mutect2
- RNF25 | c.773G>A p.R258Q | Missense Mutation (SNP) | VAF 39/91 reads (43%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.462); catalogued as rs1380847174, COSV55306267; called by muse, mutect2, varscan2
- RYR1 | c.3865C>T p.R1289W | Missense Mutation (SNP) | VAF 5/19 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs377185497, COSV62090900, COSV62101258; called by muse, mutect2, varscan2
- SH2D5 | c.1054C>T p.R352C (on ENST00000444387 / NM_001103161.2; = p.R268C on NM_001103160.2) | Missense Mutation (SNP) | VAF 41/101 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.653); catalogued as rs750727956, COSV56116220; called by muse, mutect2, varscan2
- SLC6A3 | c.1727C>A p.A576E | Missense Mutation (SNP) | VAF 19/72 reads (26%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.793); catalogued as COSV54362035; called by muse, mutect2, varscan2
- SOX5 | c.221C>T p.T74M | Missense Mutation (SNP) | VAF 49/114 reads (43%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.112); catalogued as rs776219045, COSV58619269; called by muse, mutect2, varscan2
- SPAG17 | c.5564C>T p.T1855M | Missense Mutation (SNP) | VAF 66/131 reads (50%) | SIFT deleterious (0.03); PolyPhen benign (0.407); catalogued as rs201394490; called by muse, mutect2, varscan2
- TAF1B | c.958G>T p.E320* | Nonsense Mutation (SNP) | VAF 37/82 reads (45%) | catalogued as COSV55154416, COSV55156165; called by muse, mutect2, varscan2
- TFDP1 | c.599A>T p.Q200L | Missense Mutation (SNP) | VAF 16/131 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV64739307; called by muse, mutect2, varscan2
- TMIGD1 | c.559A>T p.K187* | Nonsense Mutation (SNP) | VAF 80/289 reads (28%) | catalogued as COSV61028049; called by muse, mutect2, varscan2
- TMPO | c.1094G>T p.S365I | Missense Mutation (SNP) | VAF 33/77 reads (43%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.094); catalogued as COSV54122271; called by muse, mutect2, varscan2
- TMTC4 | c.112T>A p.Y38N (on ENST00000376234 / NM_001350577.2; = p.Y57N on NM_032813.5 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 185/243 reads (76%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.724); catalogued as COSV60891516; called by muse, mutect2, varscan2
- TNN | c.2109G>T p.K703N | Missense Mutation (SNP) | VAF 42/109 reads (39%) | SIFT tolerated (0.05); PolyPhen benign (0.365); catalogued as COSV53422506, COSV99513350; called by muse, mutect2, varscan2
- TNS1 | c.3980C>G p.S1327C | Missense Mutation (SNP) | VAF 16/42 reads (38%) | SIFT deleterious (0.03); PolyPhen benign (0.005); catalogued as COSV50692210, COSV50754660; called by muse, mutect2, varscan2
- TOGARAM2 | c.2477C>T p.A826V | Missense Mutation (SNP) | VAF 48/111 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.945); catalogued as rs368441564, COSV101090946, COSV65420120; called by muse, mutect2, varscan2
- TRIM41 | c.1490_1502del p.G497Vfs*70 | Frame Shift Del (DEL) | VAF 24/59 reads (41%) | catalogued as rs758265545; called by mutect2, pindel, varscan2
- TRPA1 | c.1156C>A p.P386T | Missense Mutation (SNP) | VAF 98/359 reads (27%) | SIFT deleterious (0.01); PolyPhen benign (0.334); catalogued as rs755719558, COSV51556355; called by muse, mutect2, varscan2
- TRPC4 | c.2055G>T p.K685N | Missense Mutation (SNP) | VAF 124/685 reads (18%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.517); catalogued as COSV58992147; called by muse, mutect2, varscan2
- TSHZ3 | c.2317A>G p.K773E | Missense Mutation (SNP) | VAF 44/153 reads (29%) | SIFT tolerated (0.35); PolyPhen benign (0.021); catalogued as COSV53665723, COSV99552535; called by muse, mutect2, varscan2
- UNC13B | c.1619C>G p.A540G | Missense Mutation (SNP) | VAF 30/64 reads (47%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.546); catalogued as COSV65931704; called by muse, mutect2, varscan2
- YTHDC2 | c.3406C>G p.R1136G | Missense Mutation (SNP) | VAF 45/130 reads (35%) | SIFT deleterious (0); PolyPhen benign (0.148); catalogued as COSV50737120; called by muse, mutect2, varscan2
- ZBTB11 | c.3092A>C p.K1031T | Missense Mutation (SNP) | VAF 79/183 reads (43%) | SIFT deleterious, low confidence (0.05); PolyPhen probably damaging (0.997); catalogued as COSV57244183; called by muse, mutect2, varscan2
- ZDHHC5 | c.1057A>G p.K353E | Missense Mutation (SNP) | VAF 21/52 reads (40%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.77); catalogued as COSV54705360; called by muse, mutect2, varscan2
- ZMYM5 | c.971A>G p.N324S | Missense Mutation (SNP) | VAF 145/251 reads (58%) | SIFT deleterious (0.04); PolyPhen benign (0.041); catalogued as COSV61987444; called by muse, mutect2, varscan2
- ZNF208 | c.3711C>G p.F1237L | Missense Mutation (SNP) | VAF 6/13 reads (46%) | SIFT tolerated (0.67); PolyPhen probably damaging (0.919); catalogued as COSV68101643; called by muse, mutect2, varscan2
- ZNF391 | c.527G>A p.R176Q | Missense Mutation (SNP) | VAF 34/74 reads (46%) | SIFT tolerated (1); PolyPhen benign (0.02); catalogued as rs775911386, COSV55121697; called by muse, mutect2, varscan2
- ZNF521 | c.2810G>A p.R937Q | Missense Mutation (SNP) | VAF 78/107 reads (73%) | SIFT tolerated (0.22); PolyPhen probably damaging (0.98); catalogued as rs1389483666, COSV64123188; called by muse, mutect2, varscan2
- CBWD5 | c.807C>G p.H269Q (on ENST00000382405 / NM_001330668.1; = p.H221Q on NM_001024916.3) | Missense Mutation (SNP) | VAF 20/125 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); called by mutect2, varscan2
- ELMO1 | c.694del p.L232Cfs*15 | Frame Shift Del (DEL) | VAF 18/51 reads (35%) | called by mutect2, pindel, varscan2
- GOLM1 | c.538A>T p.K180* | Nonsense Mutation (SNP) | VAF 34/227 reads (15%) | called by mutect2, varscan2
- INF2 | c.3635_3651del p.G1212Dfs*19 | Frame Shift Del (DEL) | VAF 26/31 reads (84%) | called by mutect2, pindel, varscan2
- RHOU | c.360C>A p.N120K | Missense Mutation (SNP) | VAF 8/190 reads (4%) | SIFT tolerated (0.07); PolyPhen benign (0.037); called by muse, mutect2
- SLAIN1 | c.710C>G p.S237C (on ENST00000466548; = p.S95C on NM_001040153.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 14/224 reads (6%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.726); called by muse, mutect2
- SLC25A5 | c.409_414del p.A137_R138del | In Frame Del (DEL) | VAF 53/143 reads (37%) | called by mutect2, pindel, varscan2
- ATXN1 | c.1884G>C p.V628= | Silent (SNP) | VAF 31/73 reads (42%) | catalogued as COSV55209170, COSV55209644; called by muse, mutect2, varscan2
- CALY | c.120G>A p.P40= | Silent (SNP) | VAF 8/20 reads (40%) | catalogued as rs780762993, COSV53309998; called by muse, varscan2
- COLGALT2 | c.1455G>T p.V485= | Silent (SNP) | VAF 78/178 reads (44%) | catalogued as COSV100730369; called by muse, mutect2, varscan2
- DAAM2 | c.150C>T p.I50= | Silent (SNP) | VAF 28/66 reads (42%) | catalogued as rs756332066, COSV51303722; called by muse, mutect2, varscan2
- DKC1 | c.1074C>T p.C358= | Silent (SNP) | VAF 76/202 reads (38%) | catalogued as rs781915787, COSV65777387; ClinVar: likely benign; called by muse, mutect2, varscan2
- EXOC5 | c.534T>C p.F178= | Silent (SNP) | VAF 59/193 reads (31%) | catalogued as COSV61770252; called by muse, mutect2, varscan2
- FBXO28 | c.1014C>T p.S338= | Silent (SNP) | VAF 55/125 reads (44%) | catalogued as rs1265726507, COSV64799812; called by muse, mutect2, varscan2
- FMO4 | c.573T>C p.G191= | Silent (SNP) | VAF 29/67 reads (43%) | catalogued as rs1443124538, COSV100882020; called by muse, mutect2, varscan2
- GRPR | c.468G>A p.K156= | Silent (SNP) | VAF 7/162 reads (4%) | catalogued as COSV100977624; called by muse, mutect2
- GSX1 | c.642C>T p.G214= | Silent (SNP) | VAF 19/71 reads (27%) | catalogued as rs1302258904, COSV57232477; called by muse, mutect2, varscan2
- H2AZ1 | c.375G>A p.Q125= | Silent (SNP) | VAF 20/185 reads (11%) | catalogued as COSV56454691; called by muse, mutect2, varscan2
- LIG4 | c.1791C>T p.D597= | Silent (SNP) | VAF 71/348 reads (20%) | catalogued as rs144253952; called by muse, mutect2, varscan2
- LILRB2 | c.822T>A p.A274= | Silent (SNP) | VAF 7/198 reads (4%) | catalogued as COSV100078966; called by muse, mutect2
- LRFN2 | c.2139G>A p.P713= | Silent (SNP) | VAF 17/38 reads (45%) | catalogued as rs377714768; called by muse, mutect2, varscan2
- LRP1B | c.9180C>T p.I3060= | Silent (SNP) | VAF 15/51 reads (29%) | catalogued as rs774022861, COSV101256803, COSV67192452; called by muse, mutect2, varscan2
- MORN1 | c.1089C>T p.G363= | Silent (SNP) | VAF 36/82 reads (44%) | catalogued as COSV66004433; called by muse, mutect2, varscan2
- MUC16 | c.18303C>A p.S6101= | Silent (SNP) | VAF 33/262 reads (13%) | catalogued as COSV101198058; called by muse, mutect2, varscan2
- MYH10 | c.4572A>G p.G1524= | Silent (SNP) | VAF 33/40 reads (83%) | catalogued as COSV52595992; called by muse, mutect2, varscan2
- MYORG | c.1755G>A p.P585= | Silent (SNP) | VAF 20/42 reads (48%) | catalogued as rs1487193392, COSV52626394; called by muse, mutect2, varscan2
- PCDHGA8 | c.543C>T p.D181= | Silent (SNP) | VAF 41/101 reads (41%) | catalogued as COSV53908822; called by muse, mutect2, varscan2
- PDE6B | c.1053C>T p.S351= | Silent (SNP) | VAF 28/62 reads (45%) | catalogued as rs768980060, COSV55324392; called by muse, mutect2, varscan2
- PIK3CG | c.1005C>T p.Y335= | Silent (SNP) | VAF 51/60 reads (85%) | catalogued as COSV63246099; called by muse, mutect2, varscan2
- POTEH | c.513C>T p.H171= | Silent (SNP) | VAF 136/1896 reads (7%) | catalogued as rs369873287; called by muse, mutect2
- RIMBP2 | c.1173G>A p.V391= | Silent (SNP) | VAF 66/149 reads (44%) | catalogued as COSV55466447; called by muse, mutect2, varscan2
- RORB | c.462C>T p.N154= (on ENST00000396204 / NM_001365023.1; = p.N143= on NM_006914.4) | Silent (SNP) | VAF 13/92 reads (14%) | catalogued as rs573233356, COSV65333322; called by muse, mutect2, varscan2
- SCN7A | c.1431G>A p.K477= | Silent (SNP) | VAF 86/203 reads (42%) | catalogued as rs1223927731, COSV69269260; called by muse, mutect2, varscan2
- SLC36A2 | c.39C>T p.A13= | Silent (SNP) | VAF 13/52 reads (25%) | catalogued as rs575961634, COSV58862290; called by muse, mutect2, varscan2
- SLC45A4 | c.2199G>A p.P733= (on ENST00000517878 / NM_001286646.2; = p.P682= on NM_001080431.2) | Silent (SNP) | VAF 31/84 reads (37%) | catalogued as rs199863585; called by muse, varscan2
- SLC6A15 | c.2049C>T p.S683= | Silent (SNP) | VAF 63/163 reads (39%) | catalogued as rs151316112; called by muse, mutect2, varscan2
- SORL1 | c.4323C>T p.Y1441= | Silent (SNP) | VAF 53/74 reads (72%) | catalogued as COSV52750317; called by muse, mutect2, varscan2
- ST6GALNAC3 | c.723C>A p.T241= | Silent (SNP) | VAF 17/53 reads (32%) | catalogued as rs767948772, COSV60322540; called by muse, mutect2, varscan2
- STAB2 | c.6396C>T p.N2132= | Silent (SNP) | VAF 5/24 reads (21%) | catalogued as rs141685973; called by muse, mutect2, varscan2
- SVEP1 | c.108C>G p.P36= | Silent (SNP) | VAF 5/16 reads (31%) | catalogued as COSV100237103; called by muse, mutect2
- TAAR5 | c.327G>A p.L109= | Silent (SNP) | VAF 47/108 reads (44%) | catalogued as COSV57798425; called by muse, mutect2, varscan2
- TNC | c.3984C>T p.G1328= | Silent (SNP) | VAF 13/35 reads (37%) | catalogued as rs554908600, COSV60781212; called by muse, mutect2, varscan2
- HERC2P3 | n.2061G>A | RNA (SNP) | VAF 40/52 reads (77%) | called by mutect2, varscan2
- MIR509-2 | n.29C>T | RNA (SNP) | VAF 121/378 reads (32%) | catalogued as rs781806712; called by mutect2, varscan2
- MIR509-3 | n.19C>T | RNA (SNP) | VAF 106/795 reads (13%) | catalogued as rs782329671; called by muse, mutect2, varscan2
- TLK1 | c.406+1146G>A | Intron (SNP) | VAF 10/28 reads (36%) | catalogued as rs372539040; called by muse, mutect2, varscan2
